Somatic mutation profile of tumor specimen ALCH-B2MA-TTP1-A (aliquot ALCH-B2MA-TTP1-A-1-0-D-A77P-36) from ALCHEMIST case ALCH-B2MA, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 78.2 years (28,577 days).
Specimen ALCH-B2MA-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1fce505b-f77d-4d60-918f-f7a446479de4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2MA-NB1-A (Blood Derived Normal), aliquot ALCH-B2MA-NB1-A-1-0-D-A77P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b613b25d-2220-4d9a-a57e-a6fbf2d49423

The open-access MAF lists 243 somatic variants for this specimen: 171 protein-altering or splice-affecting, 43 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 151, Silent 43, Intron 13, Nonsense Mutation 9, RNA 7, 3'UTR 4, Frame Shift Del 4, Splice Region 3, 5'Flank 3, Splice Site 3, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPG7 | c.1694C>T p.A565V (on ENST00000268704; = p.A572V on NM_003119.4) | Missense Mutation (SNP) | VAF 56/345 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as rs72547551, CM041075, COSV51953430; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.796G>T p.G266* | Nonsense Mutation (SNP) | VAF 86/208 reads (41%) | hotspot (GDC flag); catalogued as rs1057519990, COSV52670619, COSV52672762, COSV52751844; called by muse, mutect2, varscan2
- TSHR | c.1342G>A p.V448I | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201889708, COSV53317507; ClinVar: benign / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCC10 | c.4400G>A p.R1467H (on ENST00000372530 / NM_001198934.2; = p.R1439H on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs762227822, COSV55096107; called by muse, mutect2, varscan2
- ACSL6 | c.724G>A p.G242R (on ENST00000379240; = p.G267R on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as rs776448382, COSV99734902; called by muse, mutect2, varscan2
- ADAM21 | c.1037C>T p.T346M | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as rs757545988, COSV50807470, COSV50807988; called by muse, mutect2, varscan2
- ANKRD11 | c.2398G>A p.E800K | Missense Mutation (SNP) | VAF 62/177 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.061); catalogued as COSV99969994; called by muse, mutect2, varscan2
- ARID5B | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 53/265 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs990119259; called by muse, mutect2, varscan2
- C20orf144 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 67/920 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs1568896085; called by muse, mutect2
- CANT1 | c.1133C>T p.T378M | Missense Mutation (SNP) | VAF 47/288 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.437); catalogued as rs751200931, COSV100185370; called by muse, mutect2, varscan2
- CFAP61 | c.772G>T p.D258Y | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55640682; called by muse, mutect2, varscan2
- CROT | c.1803T>G p.H601Q | Missense Mutation (SNP) | VAF 15/222 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1167313119; called by muse, mutect2
- DMBX1 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 38/260 reads (15%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.304); catalogued as rs972701544, COSV63601903; called by muse, mutect2, varscan2
- DNAH5 | c.11654G>T p.R3885L | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV99453747; called by muse, mutect2, varscan2
- DTNA | c.1451G>A p.R484K | Missense Mutation (SNP) | VAF 78/242 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.047); catalogued as COSV52008032; called by muse, mutect2, varscan2
- ELOA | c.1175C>T p.S392F | Missense Mutation (SNP) | VAF 24/210 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV101403721; called by muse, mutect2, varscan2
- EP300 | c.29C>A p.P10Q | Missense Mutation (SNP) | VAF 198/663 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54347516; called by muse, mutect2, varscan2
- EPRS1 | c.1713G>A p.W571* | Nonsense Mutation (SNP) | VAF 34/108 reads (31%) | catalogued as rs1171673897; called by muse, mutect2, varscan2
- FBXL18 | c.1951G>T p.G651W | Missense Mutation (SNP) | VAF 180/495 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101154609; called by muse, mutect2, varscan2
- FGA | c.2234G>C p.G745A | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as COSV57399958; called by muse, mutect2, varscan2
- GALNT17 | c.1696G>A p.G566R | Missense Mutation (SNP) | VAF 145/461 reads (31%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.979); catalogued as COSV61150825; called by muse, mutect2, varscan2
- GALNT8 | c.434G>C p.R145P | Missense Mutation (SNP) | VAF 33/265 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.157); catalogued as COSV52897868; called by muse, mutect2, varscan2
- HHIPL2 | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs768313677, COSV58564731; called by muse, mutect2, varscan2
- HOMER1 | c.805A>G p.R269G | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.09); catalogued as rs536340179; called by muse, mutect2, varscan2
- IGLV4-60 | c.37C>T p.L13F | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.529); catalogued as rs1273967402; called by muse, mutect2, varscan2
- IGSF3 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 70/208 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs375715490; called by muse, mutect2, varscan2
- KCNJ3 | c.459C>A p.D153E | Missense Mutation (SNP) | VAF 30/390 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54531075; called by muse, mutect2
- KDM4C | c.2678G>A p.R893Q | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.285); catalogued as COSV67183405; called by muse, mutect2
- KIAA1549L | c.4165G>A p.G1389S (on ENST00000321505; = p.G1686S on NM_012194.3) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs752241863, COSV58590994; called by mutect2, varscan2
- MAN1C1 | c.712G>C p.E238Q | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.966); catalogued as rs1369210782; called by muse, mutect2
- NAPSA | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV99515756; called by muse, mutect2, varscan2
- NKX2-4 | c.962C>G p.A321G | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.033); catalogued as COSV104418362; called by muse, mutect2, varscan2
- NSUN3 | c.878G>T p.G293V | Missense Mutation (SNP) | VAF 48/190 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.09); catalogued as COSV58938544; called by muse, mutect2, varscan2
- NUP214 | c.4718G>T p.G1573V | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.124); catalogued as COSV63908428; called by muse, mutect2, varscan2
- OR2L2 | c.895G>T p.A299S | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as COSV100824316, COSV63549348; called by muse, varscan2
- OR2M5 | c.606C>A p.C202* | Nonsense Mutation (SNP) | VAF 64/282 reads (23%) | catalogued as COSV63545801; called by muse, mutect2, varscan2
- PAPPA2 | c.1772T>C p.I591T | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs201890893, COSV100867224; called by muse, mutect2, varscan2
- PKD2L1 | c.2248G>A p.V750M | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as rs760940072, COSV100559242; called by muse, mutect2, varscan2
- PSCA | c.127C>A p.R43S | Missense Mutation (SNP) | VAF 65/358 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.558); catalogued as COSV100008257, COSV56652700; called by muse, mutect2, varscan2
- QSER1 | c.3142A>G p.M1048V (on ENST00000399302; = p.M1177V on NM_001076786.3) | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); catalogued as rs186940689; called by muse, mutect2, varscan2
- RAD50 | c.3740A>G p.H1247R | Missense Mutation (SNP) | VAF 132/321 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.246); catalogued as rs1397349878; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RIMS2 | c.2555T>A p.L852H (on ENST00000666250 / NM_001348490.2; = p.L660H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/228 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51658224, COSV51706128; called by muse, mutect2, varscan2
- RP1 | c.4495G>T p.E1499* | Nonsense Mutation (SNP) | VAF 50/299 reads (17%) | catalogued as COSV55122805; called by muse, mutect2, varscan2
- SCARA5 | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 15/184 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as rs763502328; called by muse, mutect2
- SF1 | c.1301A>G p.Q434R | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.067); catalogued as COSV57112366; called by muse, mutect2, varscan2
- SH3KBP1 | c.1991C>G p.S664* | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as rs1191460724, COSV101115679, COSV101116442; called by muse, varscan2
- SLC35F3 | c.78G>A p.G26= (on ENST00000366617 / NM_001300845.1; = p.R95= on NM_173508.4) | Splice Region (SNP) | VAF 9/78 reads (12%) | catalogued as rs1420991687; called by muse, mutect2, varscan2
- SLCO5A1 | c.2190C>A p.N730K | Missense Mutation (SNP) | VAF 79/392 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as COSV52668177; called by muse, mutect2, varscan2
- SNTA1 | c.957G>T p.K319N | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV54131339; called by muse, mutect2
- SRRD | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as rs1187809960, COSV53227445; called by muse, mutect2, varscan2
- TBC1D1 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 48/311 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.498); catalogued as COSV54714479; called by muse, mutect2, varscan2
- TGIF2LX | c.325C>A p.L109I | Missense Mutation (SNP) | VAF 126/227 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV52213994, COSV52215515; called by muse, mutect2, varscan2
- TMEM30B | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 88/165 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs766700581; called by muse, mutect2, varscan2
- TMX2 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs775003534; called by muse, mutect2
- TRIM72 | c.218G>T p.R73L | Missense Mutation (SNP) | VAF 7/179 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.174); catalogued as rs1032425121; called by muse, mutect2
- USH2A | c.4789G>A p.D1597N | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56431208; called by muse, mutect2, varscan2
- VIRMA | c.3998C>T p.T1333M | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs769100718, COSV52586859; called by muse, mutect2
- ZFP82 | c.674T>C p.L225P | Missense Mutation (SNP) | VAF 37/264 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs867214075; called by muse, mutect2, varscan2
- ZIC4 | c.880C>A p.P294T | Missense Mutation (SNP) | VAF 142/554 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as COSV67173154; called by muse, mutect2, varscan2
- ZNF492 | c.92G>T p.W31L | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.835); catalogued as COSV71761705; called by muse, mutect2, varscan2
- ZNF837 | c.1388G>C p.R463P | Missense Mutation (SNP) | VAF 132/408 reads (32%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.843); catalogued as rs954037652, COSV69892867; called by muse, mutect2, varscan2
- ZNF91 | c.2222C>A p.P741H | Missense Mutation (SNP) | VAF 21/216 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100323645; called by muse, mutect2, varscan2
- ABCA13 | c.13232A>G p.H4411R | Missense Mutation (SNP) | VAF 37/215 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- ABCB10 | c.614T>C p.V205A | Missense Mutation (SNP) | VAF 63/222 reads (28%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCB9 | c.785G>T p.R262L | Missense Mutation (SNP) | VAF 97/313 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ABHD16B | c.1267C>G p.P423A | Missense Mutation (SNP) | VAF 30/177 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- AC100868.1 | c.1628G>C p.G543A | Missense Mutation (SNP) | VAF 9/172 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ACSL6 | c.725G>T p.G242V (on ENST00000379240; = p.G267V on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ACTN2 | c.291dup p.A98Cfs*2 | Frame Shift Ins (INS) | VAF 69/254 reads (27%) | called by mutect2, pindel, varscan2
- ADGRB1 | c.230C>A p.P77Q | Missense Mutation (SNP) | VAF 20/324 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANKRD26 | c.993G>C p.Q331H | Missense Mutation (SNP) | VAF 101/310 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ANKRD30A | c.3633A>T p.Q1211H (on ENST00000611781; = p.Q1155H on NM_052997.2) | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- ANKRD36C | c.908C>T p.S303F | Missense Mutation (SNP) | VAF 23/188 reads (12%) | SIFT deleterious (0); called by muse, varscan2
- APOL2 | c.662G>A p.G221E | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.66); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AREL1 | c.173G>C p.R58P | Missense Mutation (SNP) | VAF 147/341 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ATP2A3 | c.2038G>A p.E680K | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- BOLL | c.574G>A p.G192R | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CALCR | c.964A>G p.M322V (on ENST00000649521 / NM_001164737.2; = p.M306V on NM_001742.4) | Missense Mutation (SNP) | VAF 58/350 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- CCDC102B | c.688G>T p.G230C | Missense Mutation (SNP) | VAF 70/320 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CD207 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 187/398 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDH11 | c.586A>G p.K196E | Missense Mutation (SNP) | VAF 30/330 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.184); called by muse, mutect2
- CEP57L1 | c.18G>A p.M6I | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CFAP61 | c.904G>T p.E302* | Nonsense Mutation (SNP) | VAF 36/148 reads (24%) | called by muse, mutect2, varscan2
- CFAP69 | c.206A>C p.K69T | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- CLECL1 | c.204T>A p.F68L | Missense Mutation (SNP) | VAF 25/420 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.005); called by muse, mutect2
- CNGA4 | c.630del p.F211Lfs*17 | Frame Shift Del (DEL) | VAF 25/199 reads (13%) | called by mutect2, pindel, varscan2
- COL4A1 | c.2096G>T p.G699V | Missense Mutation (SNP) | VAF 170/402 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL6A5 | c.226G>T p.D76Y | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CPEB3 | c.818G>A p.G273D | Missense Mutation (SNP) | VAF 62/331 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- CUL3 | c.604G>T p.E202* | Nonsense Mutation (SNP) | VAF 33/113 reads (29%) | called by muse, mutect2, varscan2
- CYTIP | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, varscan2
- DACT3 | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 37/227 reads (16%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- DNHD1 | c.9669+7T>G | Splice Region (SNP) | VAF 77/289 reads (27%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.3925A>T p.T1309S | Missense Mutation (SNP) | VAF 16/177 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.001); called by muse, mutect2
- ECM1 | c.1264A>T p.M422L | Missense Mutation (SNP) | VAF 149/454 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.275); called by muse, mutect2
- ECSIT | c.711C>G p.D237E | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ELAVL4 | c.143T>A p.L48H | Missense Mutation (SNP) | VAF 46/450 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ENPP2 | c.972G>C p.E324D | Missense Mutation (SNP) | VAF 13/205 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2
- EZH1 | c.1355A>G p.N452S | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); called by mutect2, varscan2
- FAM120C | c.917T>A p.M306K | Missense Mutation (SNP) | VAF 78/104 reads (75%) | SIFT tolerated (0.65); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- FAM135B | c.4129C>A p.L1377M | Missense Mutation (SNP) | VAF 250/579 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAM90A10P | c.1148C>A p.A383E | Missense Mutation (SNP) | VAF 86/493 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GPR85 | c.153G>T p.L51F | Missense Mutation (SNP) | VAF 104/314 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GRM5 | c.2061C>A p.F687L | Missense Mutation (SNP) | VAF 67/165 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- HDAC4 | c.2373+8G>T | Splice Region (SNP) | VAF 59/158 reads (37%) | called by muse, mutect2, varscan2
- HDGFL2 | c.1141G>T p.V381F | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- HYDIN | c.13334A>G p.N4445S | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- JAK3 | c.1342A>T p.S448C | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- JPH2 | c.1538A>G p.N513S | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- KATNIP | c.1412A>G p.D471G | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, varscan2
- KCNK10 | c.1528C>G p.Q510E | Missense Mutation (SNP) | VAF 54/432 reads (13%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIR3DL2 | c.475G>T p.G159W | Missense Mutation (SNP) | VAF 149/520 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- KLRF1 | c.76A>T p.T26S | Missense Mutation (SNP) | VAF 65/113 reads (58%) | SIFT tolerated (0.66); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- KMT2C | c.964C>A p.H322N | Missense Mutation (SNP) | VAF 53/522 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, varscan2
- KRT13 | c.736-2A>G p.X246_splice | Splice Site (SNP) | VAF 49/177 reads (28%) | called by muse, mutect2, varscan2
- KRT28 | c.451-1G>T p.X151_splice | Splice Site (SNP) | VAF 40/124 reads (32%) | called by muse, mutect2, varscan2
- LDLRAD4 | c.767G>A p.S256N | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- LONP2 | c.1801A>G p.R601G | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LRRC15 | c.417G>C p.Q139H | Missense Mutation (SNP) | VAF 181/396 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- MGAM2 | c.4842C>G p.I1614M | Missense Mutation (SNP) | VAF 13/276 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); called by muse, mutect2
- MOGAT3 | c.416C>A p.P139Q | Missense Mutation (SNP) | VAF 104/384 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRC1 | c.1764C>A p.H588Q | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- MRGPRD | c.691C>A p.L231I | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- MRTFB | c.3073_3077del p.M1025Gfs*61 (on ENST00000571589 / NM_001365412.2; = p.M975Gfs*61 on NM_014048.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 33/134 reads (25%) | called by pindel, varscan2
- MSL1 | c.707A>G p.Q236R | Missense Mutation (SNP) | VAF 74/674 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); called by mutect2, varscan2
- MTM1 | c.232-2A>G p.X78_splice | Splice Site (SNP) | VAF 87/124 reads (70%) | called by muse, mutect2, varscan2
- MYH7B | c.3962C>T p.A1321V | Missense Mutation (SNP) | VAF 32/216 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRC3 | c.479G>T p.R160L | Missense Mutation (SNP) | VAF 80/301 reads (27%) | SIFT tolerated (0.69); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- NOL9 | c.1778G>A p.G593E | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- NOP53 | c.964G>T p.A322S | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NRXN2 | c.176C>A p.T59N | Missense Mutation (SNP) | VAF 165/402 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NXPE1 | c.351G>T p.Q117H | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- OR8B4 | c.71A>G p.Q24R | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PADI6 | c.392A>T p.Y131F | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.936); called by muse, varscan2
- PAPPA2 | c.1400G>T p.W467L | Missense Mutation (SNP) | VAF 22/415 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- PCF11 | c.1922A>G p.Q641R | Missense Mutation (SNP) | VAF 62/174 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- PCNX1 | c.5282G>T p.S1761I | Missense Mutation (SNP) | VAF 17/169 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PHRF1 | c.3218A>G p.K1073R (on ENST00000264555 / NM_001286581.2; = p.K1072R on NM_020901.4) | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- PIWIL1 | c.277A>G p.T93A | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POU3F3 | c.479C>A p.A160E | Missense Mutation (SNP) | VAF 74/174 reads (43%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTPRU | c.1536G>T p.E512D | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RCAN2 | c.404T>C p.L135P | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- RGSL1 | c.891G>A p.M297I | Missense Mutation (SNP) | VAF 148/254 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- RIOX2 | c.1075A>T p.R359W (on ENST00000333396 / NM_001042533.2; = p.R358W on NM_032778.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- RPH3A | c.822G>T p.Q274H (on ENST00000389385 / NM_001143854.2; = p.Q270H on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.656); called by muse, varscan2
- SALL1 | c.717G>C p.Q239H | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SEL1L | c.648del p.M216Ifs*34 | Frame Shift Del (DEL) | VAF 9/96 reads (9%) | called by mutect2, pindel, varscan2
- SETD1A | c.144T>G p.S48R | Missense Mutation (SNP) | VAF 62/229 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- SIX3 | c.179G>A p.G60D | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- SLC28A3 | c.989C>T p.S330F | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SORCS3 | c.1370A>G p.D457G | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, varscan2
- SPRYD7 | c.571T>C p.F191L | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- SYT9 | c.617G>T p.R206M | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- TAF6 | c.1157A>G p.D386G | Missense Mutation (SNP) | VAF 69/206 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- TAOK2 | c.2231A>T p.K744I | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- TAS2R9 | c.733T>C p.Y245H | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TESC | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 22/88 reads (25%) | called by muse, mutect2, varscan2
- TFDP3 | c.476del p.N159Tfs*2 | Frame Shift Del (DEL) | VAF 82/241 reads (34%) | called by mutect2, pindel, varscan2
- THBS1 | c.2208T>A p.D736E | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TMEM196 | c.113G>T p.R38L | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TNC | c.4003A>C p.T1335P | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2
- TTLL3 | c.2579A>T p.D860V | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TTN | c.23066G>T p.C7689F (on ENST00000591111; = p.C6762F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/281 reads (17%) | PolyPhen probably damaging (0.997); called by muse, mutect2
- VEPH1 | c.763C>A p.L255I | Missense Mutation (SNP) | VAF 58/290 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- VWA5B2 | c.1697G>A p.G566D | Missense Mutation (SNP) | VAF 17/187 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.186); called by muse, mutect2
- WDR13 | c.956T>A p.L319H | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- WDR72 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 58/275 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- XIRP2 | c.6715G>T p.G2239* (on ENST00000628543; = p.G2414* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 78/176 reads (44%) | called by mutect2, varscan2
- XKR7 | c.937C>A p.R313S | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZIC4 | c.881C>A p.P294H | Missense Mutation (SNP) | VAF 143/556 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- ZNF721 | c.1327A>G p.I443V (on ENST00000338977; = p.I455V on NM_133474.4) | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- AASDH | c.1059G>T p.A353= | Silent (SNP) | VAF 31/95 reads (33%) | catalogued as COSV99221265; called by muse, mutect2, varscan2
- ADAM29 | c.1902C>T p.G634= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as rs184911763; called by muse, mutect2, varscan2
- APOL2 | c.663G>T p.G221= | Silent (SNP) | VAF 27/112 reads (24%) | called by muse, mutect2, varscan2
- APPL1 | c.1293A>G p.L431= | Silent (SNP) | VAF 17/48 reads (35%) | called by muse, mutect2, varscan2
- ATG2A | c.3457C>T p.L1153= | Silent (SNP) | VAF 31/163 reads (19%) | catalogued as rs1333298692, COSV65968865; called by muse, mutect2, varscan2
- AVL9 | c.936C>T p.T312= | Silent (SNP) | VAF 28/100 reads (28%) | called by muse, varscan2
- AXIN2 | c.2274G>T p.A758= | Silent (SNP) | VAF 94/359 reads (26%) | catalogued as COSV61059857; called by muse, mutect2, varscan2
- CCDC168 | c.6690G>A p.A2230= | Silent (SNP) | VAF 41/241 reads (17%) | catalogued as rs373854930; called by muse, mutect2, varscan2
- CDH23 | c.9048C>A p.R3016= | Silent (SNP) | VAF 41/112 reads (37%) | catalogued as rs538058499; called by muse, mutect2, varscan2
- EPHA5 | c.276T>C p.N92= | Silent (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2, varscan2
- FGF4 | c.399C>T p.S133= | Silent (SNP) | VAF 24/219 reads (11%) | called by muse, mutect2, varscan2
- GABRB2 | c.1410C>T p.R470= (on ENST00000274547; = p.R432= on NM_000813.3) | Silent (SNP) | VAF 26/212 reads (12%) | catalogued as rs373821165; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLI1 | c.2478C>T p.S826= | Silent (SNP) | VAF 11/40 reads (28%) | called by muse, mutect2, varscan2
- HOXD11 | c.516C>T p.G172= | Silent (SNP) | VAF 170/775 reads (22%) | catalogued as rs1431632678; called by muse, mutect2, varscan2
- HSPBP1 | c.963C>G p.L321= | Silent (SNP) | VAF 29/237 reads (12%) | catalogued as COSV55335049; called by muse, mutect2, varscan2
- IFT43 | c.315T>C p.D105= (on ENST00000314067 / NM_001102564.3; = p.D110= on NM_052873.3) | Silent (SNP) | VAF 147/335 reads (44%) | catalogued as rs59175852; called by muse, mutect2, varscan2
- MACF1 | c.1749A>G p.E583= | Silent (SNP) | VAF 32/163 reads (20%) | called by muse, mutect2, varscan2
- MIGA2 | c.1158C>T p.T386= | Silent (SNP) | VAF 14/121 reads (12%) | called by muse, mutect2, varscan2
- MSI1 | c.831G>C p.A277= | Silent (SNP) | VAF 47/246 reads (19%) | called by muse, mutect2, varscan2
- MUC16 | c.2208A>G p.K736= | Silent (SNP) | VAF 63/206 reads (31%) | called by muse, mutect2, varscan2
- NPR2 | c.414C>T p.T138= | Silent (SNP) | VAF 301/948 reads (32%) | catalogued as rs563276788; called by muse, mutect2, varscan2
- OR2L2 | c.336G>T p.L112= | Silent (SNP) | VAF 72/226 reads (32%) | called by muse, mutect2, varscan2
- OR4C6 | c.855T>C p.Y285= | Silent (SNP) | VAF 28/136 reads (21%) | catalogued as rs371988382; called by muse, mutect2, varscan2
- PDZD2 | c.2133T>C p.S711= | Silent (SNP) | VAF 20/274 reads (7%) | called by muse, mutect2
- PNLIP | c.675C>T p.P225= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as COSV65041524; called by muse, varscan2
- PRKRIP1 | c.39G>A p.R13= | Silent (SNP) | VAF 41/242 reads (17%) | called by muse, mutect2, varscan2
- RAPGEF5 | c.156C>A p.R52= | Silent (SNP) | VAF 183/568 reads (32%) | catalogued as COSV59782449; called by muse, mutect2, varscan2
- REG3A | c.216C>T p.P72= | Silent (SNP) | VAF 78/151 reads (52%) | called by muse, mutect2, varscan2
- RELN | c.1101G>T p.V367= | Silent (SNP) | VAF 140/444 reads (32%) | called by muse, mutect2, varscan2
- RNF43 | c.2298G>A p.S766= | Silent (SNP) | VAF 6/116 reads (5%) | catalogued as rs1203633419; called by muse, mutect2
- SALL1 | c.150C>G p.A50= | Silent (SNP) | VAF 24/268 reads (9%) | called by muse, mutect2
- SH3TC2 | c.3646C>T p.L1216= | Silent (SNP) | VAF 16/260 reads (6%) | catalogued as rs1450566312; called by muse, mutect2
- SLC7A2 | c.1020C>T p.V340= (on ENST00000494857 / NM_001370338.1; = p.V380= on NM_003046.6) | Silent (SNP) | VAF 27/158 reads (17%) | catalogued as rs770199056; called by muse, mutect2, varscan2
- SOX11 | c.201C>A p.I67= | Silent (SNP) | VAF 30/374 reads (8%) | called by muse, mutect2
- SPRR3 | c.273C>A p.T91= | Silent (SNP) | VAF 117/434 reads (27%) | catalogued as COSV99768373; called by muse, varscan2
- STAB1 | c.375C>A p.T125= | Silent (SNP) | VAF 18/158 reads (11%) | called by muse, mutect2, varscan2
- TKFC | c.465C>T p.C155= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as rs905212953; called by muse, mutect2, varscan2
- TTC30A | c.48G>T p.A16= | Silent (SNP) | VAF 81/353 reads (23%) | catalogued as rs572372097; called by muse, mutect2, varscan2
- TTN | c.78879C>T p.F26293= (on ENST00000591111; = p.F18869= on NM_003319.4) | Silent (SNP) | VAF 12/74 reads (16%) | called by muse, mutect2, varscan2
- UNKL | c.1641C>A p.P547= | Silent (SNP) | VAF 23/203 reads (11%) | called by muse, mutect2, varscan2
- URB1 | c.3534C>T p.S1178= | Silent (SNP) | VAF 64/241 reads (27%) | catalogued as rs750553848; called by mutect2, varscan2
- ZFHX4 | c.5961G>A p.E1987= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as rs1188379673; called by muse, mutect2
- ZNF610 | c.150G>A p.R50= | Silent (SNP) | VAF 30/124 reads (24%) | called by muse, mutect2, varscan2
- AC136628.2 | n.1038_1039del | RNA (DEL) | VAF 39/140 reads (28%) | called by mutect2, pindel, varscan2
- ANK1 | c.5395-1176G>T | Intron (SNP) | VAF 118/659 reads (18%) | called by muse, mutect2, varscan2
- ANKRD42 | chr11:83194162 A>G | 5'Flank (SNP) | VAF 41/123 reads (33%) | called by muse, mutect2, varscan2
- C17orf67 | c.-46A>G | 5'UTR (SNP) | VAF 41/140 reads (29%) | catalogued as rs780756078; called by muse, mutect2, varscan2
- CES4A | c.260+318C>A | Intron (SNP) | VAF 8/22 reads (36%) | called by muse, varscan2
- CSF2RA | c.647-35C>T | Intron (SNP) | VAF 46/153 reads (30%) | catalogued as rs775321600; called by muse, mutect2, varscan2
- FERMT3 | c.1080-40T>C | Intron (SNP) | VAF 35/323 reads (11%) | called by muse, mutect2, varscan2
- FUNDC2P2 | n.138T>A | RNA (SNP) | VAF 16/108 reads (15%) | called by muse, mutect2
- KIF15 | c.2383+13A>C | Intron (SNP) | VAF 6/22 reads (27%) | called by muse, varscan2
- KLHL22 | c.-34+2574C>T | Intron (SNP) | VAF 32/165 reads (19%) | called by muse, mutect2, varscan2
- LAD1 | c.*42G>T | 3'UTR (SNP) | VAF 194/441 reads (44%) | called by muse, mutect2, varscan2
- LINC01548 | n.548G>T | RNA (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- MIR758 | n.13G>A | RNA (SNP) | VAF 6/66 reads (9%) | catalogued as rs1324688260; called by muse, mutect2, varscan2
- MIRLET7A3 | chr22:46109976 G>T | 5'Flank (SNP) | VAF 75/259 reads (29%) | called by muse, mutect2, varscan2
- NR2F2-AS1 | n.945C>T | RNA (SNP) | VAF 14/154 reads (9%) | catalogued as rs1456201272; called by muse, mutect2
- NUDCD1 | c.118+4029A>T | Intron (SNP) | VAF 16/96 reads (17%) | catalogued as COSV53456156; called by muse, mutect2, varscan2
- ORC6 | c.*359A>G | 3'UTR (SNP) | VAF 4/29 reads (14%) | called by muse, varscan2
- RIN3 | c.2631+75G>T | Intron (SNP) | VAF 6/12 reads (50%) | catalogued as COSV53646255; called by muse, mutect2, varscan2
- SNORD115-7 | n.17T>C | RNA (SNP) | VAF 26/167 reads (16%) | called by muse, mutect2, varscan2
- SOST | c.*12G>C | 3'UTR (SNP) | VAF 31/71 reads (44%) | catalogued as rs767740445; called by muse, mutect2, varscan2
- TTC7B | c.699-3620C>A | Intron (SNP) | VAF 16/204 reads (8%) | called by muse, mutect2
- TTN | c.10360+5437C>A | Intron (SNP) | VAF 22/257 reads (9%) | called by muse, mutect2
- TTN | c.10360+5436C>A | Intron (SNP) | VAF 24/254 reads (9%) | called by muse, mutect2
- UBBP4 | n.735C>A | RNA (SNP) | VAF 128/349 reads (37%) | called by muse, varscan2
- VOPP1 | c.54+10306C>A | Intron (SNP) | VAF 22/166 reads (13%) | catalogued as rs771099407, COSV53384618; called by muse, mutect2, varscan2
- Y_RNA | chr7:74896164 A>G | 3'Flank (SNP) | VAF 8/20 reads (40%) | catalogued as rs1206685589; called by mutect2, varscan2
- ZC3H14 | c.2006-17G>T | Intron (SNP) | VAF 118/264 reads (45%) | called by muse, mutect2, varscan2
- ZNF208 | c.*543A>T | 3'UTR (SNP) | VAF 16/159 reads (10%) | called by muse, mutect2
- ZWINT | chr10:56361266 C>A | 5'Flank (SNP) | VAF 17/121 reads (14%) | called by muse, mutect2, varscan2
